Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4965, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4965-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

TCGA - BP - 4965

Clinical Diagnosis & History:

with incidental left renal mass.

Specimens Submitted:

1: Kidney, left, partial nephrectomy

2: Kidney, deep margin #2, excision

3: Kidney, satellite tumor #1, biopsy

DIAGNOSIS:

1. Kidney, left, partial nephrectomy

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 1.9 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Renal vein is not identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

2. Kidney, deep margin #2, excision

Benign renal parenchyma and perirenal fat

[page 2 of 3]
3. Kidney, satellite tumor #1, biopsy (sr):

Tubulopapillary neoplasm, 0.2 cm, consistent with the so called papillary adenoma.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1) The specimen is received fresh for frozen section consultation, labeled "Left renal tumor, freeze stitched deep margin". It consists of a 4.8 x 3.7 x 2.3 cm segment of renal parenchyma with an attached black suture at the margin. The resected margin is inked black. The outer surface of the perinephric fat is inked blue. A cut section of the specimen shows a 1.9 x 1.6 x 1.5 cm partially cystic bright orange hemorrhagic tumor. It is located less than 1 mm from the inked margin. The remainder of the renal parenchyma is brown-tan and unremarkable. A representative section of the tumor is frozen. Representative sections are submitted. A sample of the tumor is given to TPS.

Summary of sections:

FSC - frozen section control

T - tumor

U - undesignated

2) Specimen is received in formalin labeled "Deep margin #2" and consists of a 4.5 x 2.5 x 2.5 cm tissue fragment, represented by 0.5 cm thick perirenal fat and 2 cm thick conical renal parenchyma. A second tissue fragment in the container consists of perirenal fat measuring 4.0 x 2.8 x 0.5 cm. The perirenal surface is inked black, the renal parenchymal surface is inked green. The specimen is serially sectioned and representatively submitted.

Summary of sections:

LF - large fragment with renal parenchyma

SF - small fragment of white perirenal fat

3) Specimen is received in formalin labeled "Satellite tumor #1" and consists of a 0.4 cm brown tissue fragment. Entirely submitted.

Summary of sections.

ET - entire tissue

Summary of Sections:

Part 1: Kidney, left, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
3	t	3
1	u	1

Part 2: Kidney, deep margin #2, excision

Block	Sect. Site	PCs
3	LF	3
1	SF	3

[page 3 of 3]
Part 3: Kidney, satellite tumor #1, biopsy

Block	Sect. Site	PCs
1	ET	1

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: MARGIN NEGATIVE; FAVOR CLEAR CELL CARCINOMA
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 693699d2-9500-4ad4-ac53-5a7d1bcc6717 (TCGA-BP-4965.2D4E72C2-AD88-4E2B-95DC-BA8CBD84AF92.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).